Surgical pathology report (de-identified scan), TCGA case TCGA-BP-4787, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-4787-01A (Primary Tumor).

[page 1 of 3]
TCGA-BP-4787

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

Ref. Source:

Clinical Diagnosis & History:

with left renal mass biopsy proven conv.

Specimens Submitted:

1: KIDNEY; TOTAL NEPHRECTOMY

2: LYMPH NODES, PARA-AORTIC, EXCISION

3: LYMPH NODES, SUPRAHILAR PARA-AORTIC, EXCISION

DIAGNOSIS:

1. KIDNEY; TOTAL NEPHRECTOMY

Tumor Type:

Renal cell carcinoma - Conventional (clear cell) type

Fuhrman Nuclear Grade:

Nuclear grade IV/IV

Tumor Size:

Greatest diameter is 9.5 cm.

Local Invasion (for renal cortical types):

Extends through renal capsule but confined within Gerota's fascia

Renal Vein Invasion:

Not identified

Surgical Margins:

Free of tumor

Non-Neoplastic Kidney:

Unremarkable

Adrenal Gland:

Not involved

Lymph Nodes:

Free of tumor

Number of nodes examined:3

See part 2 also

Staging for renal cell carcinoma/oncocytoma:

pT3a Tumor invades the adrenal gland or perinephric tissues but not beyond Gerota's fascia

2. LYMPH NODES, PARA-AORTIC, EXCISION

[page 2 of 3]
[REDACTED]

Lymph Nodes:
Not Involved
Number of nodes examined:15

3. LYMPH NODES, SUPRAHILAR PARA-AORTIC, EXCISION [REDACTED]

Lymph Nodes:
Not Involved
Number of nodes examined:1

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

[REDACTED]

Special Studies:

Result	Special Stain	Comment
	CHR	
	SYN	
	NEG CONT	
	IMM RECUT	
	RECUT	
	RECUT	
	RECUT	
	RECUT	
	RECUT	

Gross Description:

[REDACTED]

1). The specimen is received fresh, labeled "left kidney" and consists of a kidney with attached ureter, renal vessels and perinephric fat weighing 648 g in total. The kidney measures 14.5 x 8.5 x 8 cm. The attached ureter measures 4.5 cm in length and 0.5 cm in diameter. The attached renal vein measures 0.5 cm in length and 0.7 cm in diameter. The renal vessels and ureter margins are grossly unremarkable. An adrenal gland is identified, measuring 4.5 x 3.5 x 1 cm. The kidney is inked black and bivalved to reveal 9.5 X 7.5 X 5 cm yellow -- white relatively well-circumscribed tumor occupying the upper pole of the specimen and extending into perinephric fat. The tumor shows multifocal areas of necrosis and hemorrhage. Sections through the remainder of the kidney reveal a pink-brown parenchyma, with a well-defined cortico-medullary junction. The cortex measures 1.3 cm and the calyces appear normal. Few lymph nodes are identified in the perinephric fat. Representative sections are submitted for TPS and for permanent sections.

Summary of sections:

UVM -- ureteral and vessel margins
LN- lymph nodes
T-- tumor
THF-- tumor with hilar fat
TK -- tumor with adjacent kidney
RP -- renal pelvis representative sections
K -- representative sections kidney
AD -- adrenal gland

[REDACTED]

2).The specimen is received in formalin labeled, "para-aortic lymph nodes", and consists of a single piece of yellow -- gold and red ten soft tissue measuring 6.5 x 2 x 1.8 cm. Multiple lymph nodes are identified ranging in size from 0.3 to 1 cm in greatest dimension and are submitted.

Summary of sections:

[page 3 of 3]
LN -- lymph nodes

3). The specimen is received in formalin labeled, "suprahilar para-aortic tissue", and consists of a single piece of red tan soft tissue measuring 1.2 x 0.6 x 0.6 cm. Entirely submitted.

Summary of sections:

U-- undesignated

Summary of Sections:

Part 1: KIDNEY; TOTAL NEPHRECTOMY

Block	Sect. Site	PCs
1	ad	1
1	k	1
1	ln	3
1	pr	1
5	t	5
1	thf	1
3	tk	3
1	uvm	3

Part 2: LYMPH NODES, PARA-AORTIC, EXCISION

Block	Sect. Site	PCs
4	LN	4

Part 3: LYMPH NODES, SUPRAHILAR PARA-AORTIC, EXCISION

Block	Sect. Site	PCs
1	U	1

Source: NCI Genomic Data Commons file 256aac8b-e98e-4dbb-8ca5-866a42c004ae (TCGA-BP-4787.76E2AAD5-00D1-4D94-878B-2AF2B403F958.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).